Surgical pathology report (de-identified scan), TCGA case TCGA-EU-5906, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site CHI-Penrose Colorado, specimen TCGA-EU-5906-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

SPECIMEN

A. KIDNEY - 1. Left kidney - Not in formalin

CLINICAL INFORMATION

Mass – left kidney

GROSS DESCRIPTION

The specimen is received fresh labeled [REDACTED] "left kidney" and consists of a 560 gm, 15.7 x 11.6 x 5.8 cm kidney encased in perirenal fat. The specimen is bivalved to reveal a 13.1 x 7.6 cm tan-red kidney with a 5.9 x 4.7 x 4.6 cm bright yellow, partially hemorrhagic and cystic, well-circumscribed mass occupying the upper pole. Representative sections of tumor and benign kidney are submitted for the TCGA genome project. The remainder of the kidney is placed into formalin and fixed overnight. The hilar structures are identified and opened and reveal no gross involvement by tumor. A shave margin of the ureter and hilar vessels are removed. A search for hilar lymph nodes does not show any recognizable lymph node structures. The perirenal fat overlying the tumor is inked black. Serial sectioning through the tumor demonstrates the tumor to be grossly confined to the renal cortex and within the renal capsule. No involvement or invasion through the renal capsule is identified. However, the tumor does extend to the renal capsule and abuts the capsule grossly. Sectioning shows no involvement of the tumor into the renal pelvis or renal vasculature. The tumor lies 0.3 cm from the nearest renal pelvis, 1.4 cm from the closest renal vein, and 0.6 cm from the nearest renal artery. The cut surface of the tumor demonstrates a bright yellow, partially cystic and hemorrhagic surface with focal areas of calcification. The remainder of the kidney uninvolved by tumor demonstrates an unremarkable tan-red cut surface with well-defined corticomedullary junctions, with an average cortical thickness of 0.8 cm.

SLIDE KEY:

- A1 – hilar vessels and ureter
- A2 – hilar fat
- A3-A6 – tumor in areas closest to renal capsule
- A7 – tumor closest to renal pelvis
- A8 – tumor adjacent to benign kidney with closest renal artery
- A9 – benign uninvolved kidney

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Representative H&E-stained tissue sections were examined that show a neoplastic proliferation of clear cells with moderate to large amounts of lightly eosinophilic to clear cytoplasm and nuclei that are small to slightly increased in size. Many of the nuclei are round and regular with smooth nuclear membranes and indistinct nucleoli (Fuhrman nuclear grade 1). Other nuclei are slightly enlarged, have slightly irregular nuclear membranes, and discernible nucleoli at 400x (Fuhrman nuclear grade 2). Please see the following Cancer Case Summary for specific details.

CANCER CASE SUMMARY, KIDNEY

PROCEDURE: Radical nephrectomy.

SPECIMEN LATERALITY: Left.

TUMOR SITE: Upper pole.

TUMOR SIZE:

Greatest dimension: 5.9 cm.

Additional dimensions: 4.7 x 4.6 cm.

TUMOR FOCALITY: Unifocal.

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney.

HISTOLOGIC TYPE: Clear cell renal cell carcinoma.

SARCOMATOID FEATURES: Not identified.

TUMOR NECROSIS: Not identified.

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): G2.

MICROSCOPIC TUMOR EXTENSION: Tumor limited to kidney.

MARGINS: Margins uninvolved by invasive carcinoma.

LYMPH-VASCULAR INVASION: Not identified.

PATHOLOGIC STAGING:

Primary tumor: pT1b

Regional lymph nodes: pNX.

Distant metastasis: Not applicable.

PATHOLOGIC FINDINGS IN NON-NEOPLASTIC KIDNEY: Mild to moderate arteriosclerosis.

FINAL DIAGNOSIS

LEFT KIDNEY, RADICAL NEPHRECTOMY

- **CLEAR CELL RENAL CELL CARCINOMA, FUHRMAN NUCLEAR GRADE G2.**

- Please see Cancer Case Summary for specific details.

CPT CODE(S): 88307x1

Source: NCI Genomic Data Commons file d440fb7e-8187-4144-8a3c-fcfc0b3f0b9c (TCGA-EU-5906.EC4BE720-05D2-430E-AE07-986302672F4E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).